Gene-level copy-number profile of tumor specimen TARGET-10-PATBGC-09A from TARGET case TARGET-10-PATBGC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.8 years (3,946 days).
Specimen TARGET-10-PATBGC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.0f2a6a11-088e-5207-9aaa-bf1c8c1a018a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATBGC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate.
https://portal.gdc.cancer.gov/files/058e2dfd-0f9f-4ffe-bb01-89bc4904c48e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 539; copy number 1: 179; copy number 2: 59,337; copy number 3: 19; copy number 4: 193; copy number 5: 4; copy number 6: 2; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:74,084,068–74,103,216, 1 gene (within-gene range 0–2): LINC02122.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr6:30,516,266–30,557,174, 2 genes: LINC02569, GNL1.
- chr6:79,854,684–80,042,527, 8 genes: AL132875.1, AL132875.3, AL132875.2, ELOVL4, AL133475.1, GAPDHP63, RPL35AP18, TTK.
- chr10:48,835,541–48,845,945, 1 gene: AC035139.2.
- chr12:4,649,095–4,694,317, 1 gene (within-gene range 0–2): NDUFA9.
- chr17:40,977,716–40,987,135, 1 gene (within-gene range 0–2): KRT40.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:116,742,991–116,762,209, 1 gene, copy number 5 (within-gene range 2–5): LINC02214.
- chr6:166,098,111–166,099,589, 1 gene, copy number 6: AL627443.3.
- chr6:166,099,853–166,099,924, 1 gene, copy number 6: AL627443.2.
- chr13:29,918,647–29,926,651, 1 gene, copy number 5 (within-gene range 1–5): LINC00572.
- chr13:59,262,680–59,263,391, 1 gene, copy number 7: RPP40P2.
- chr15:45,430,652–45,441,808, 2 genes, copy number 5 (within-gene range 3–5): AC025580.1, MIR147B.

Autosomal genes at a single copy (total copy number 1): 179. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
